Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADN, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADN-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Right hemihepatectomy

Organs:

Liver (14.5 x 15.0 x 8.0 cm, 798.0 gm)

Gallbladder (11.0 cm in length, 3.5 cm in diameter, and 0.3 cm in thickness)

Lesion: A well-defined mass (14.5 x 8.0 x 7.0 cm)

Cut surface: Yellowish tan, solid and firm mass with area of hemorrhage
and necrosis

Gross type: Multinodular confluent

Resection margin: Not involved grossly (safety margin: 3.0 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Cross photo: Present

Blocks

T1-5, TB, tumor mass x 6

L, liver parenchyma x 1

RM, resection margin x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation IV

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (20 %)

Fibrous capsule formation: Complete capsule

Capsular infiltration: Yes

Septum formation: No

Surgical resection margin invasion: No, safety margin (3.0 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: Yes

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

NOT reported. Gross:

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Date: June 22.0

7/5/2014

[page 2 of 2]
Liver, ectomy, hepatocellular carcinoma, cirrhosis

T56000, P10, M81703, M49500

Gallbladder, ectomy, autolysis

T57000, P10, M54001

DIAGNOSIS:

Liver, segment 5-8, right hemihepatectomy:

Hepatocellular carcinoma (see NOTE)

Cirrhosis

Gallbladder, cholecystectomy:

Autolysis

NOTE:

Recommend to order the IHC stains (Hepatocyte, Glypican3, CD34, p53, CK7, EBV, and hHCG) on block T1 to differentiate from other malignant tumors.

Suggestion :

Source: NCI Genomic Data Commons file 38c7511e-c805-425e-921d-2d56d442d9cf (TCGA-DD-AADN.043E7A50-2122-42D4-BB6F-9AAC61FE8CBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).